Gene-level copy-number profile of tumor specimen TCGA-B8-5163-01A from TCGA case TCGA-B8-5163, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 63.8 years (23,293 days).
Specimen TCGA-B8-5163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.cf625520-4c28-4208-8eb3-9c5b49bbedbb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B8-5163-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d5679c6-4039-44b0-808b-f03da903628b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,938; copy number 2: 43,998; copy number 3: 6,828; copy number 4: 2,985; copy number 16: 33; copy number 17: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B8-5163-01A-01D-1417-01): tumor purity 0.34, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 71 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,375,580–155,854,456, 13 genes, copy number 16 (within-gene range 3–16): PLCH1, AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2, RPL6P7, AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1.
- chr3:169,083,499–170,454,733, 35 genes, copy number 17 (within-gene range 1–17): MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,423,103–170,423,162, 1 gene, copy number 17: MIR6828.
- chr3:170,459,548–170,586,075, 2 genes, copy number 17: SLC7A14, KRT8P13.
- chr3:178,028,130–179,394,936, 18 genes, copy number 16 (within-gene range 1–16): AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1.
- chr3:179,396,961–179,405,944, 2 genes, copy number 16: AC007620.2, AC007620.3.

Autosomal genes at a single copy (total copy number 1): 5,938. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
